Somatic mutation profile of tumor specimen TCGA-19-1786-01A (aliquot TCGA-19-1786-01A-01W-0643-08) from TCGA case TCGA-19-1786, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 64.5 years (23,568 days).
Specimen TCGA-19-1786-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e44173c6-63c9-407e-ac31-e6960af7ee52.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-19-1786-10A (Blood Derived Normal), aliquot TCGA-19-1786-10A-01W-0643-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6168b1f3-8ebc-464d-af0c-01e85c82c96b

The open-access MAF lists 59 somatic variants for this specimen: 44 protein-altering or splice-affecting, 12 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 12, Nonsense Mutation 4, 3'UTR 1, Intron 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRF5 | c.3133C>T p.R1045W | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs200682859, COSV51930087; called by muse, mutect2, varscan2
- AOX1 | c.3692G>A p.R1231H | Missense Mutation (SNP) | VAF 123/221 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as rs373230627; called by muse, mutect2, varscan2
- BATF2 | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367686912; called by muse, varscan2
- BMP3 | c.1408G>A p.A470T | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763946969, COSV51081761; called by muse, mutect2, varscan2
- BRINP2 | c.623C>T p.T208M | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs760695139, COSV64175242, COSV64175962; called by muse, mutect2, varscan2
- CBX7 | c.230A>G p.K77R | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs17857402, COSV99334149; called by muse, varscan2
- CCIN | c.896C>G p.A299G | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.956); catalogued as COSV100631914, COSV58725850; called by muse, mutect2, varscan2
- CCIN | c.1693C>G p.P565A | Missense Mutation (SNP) | VAF 63/168 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as COSV58724116; called by muse, varscan2
- CD163L1 | c.253G>A p.V85M | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs370414180; called by muse, mutect2, varscan2
- CFAP206 | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781384108, COSV51532655; called by muse, mutect2, varscan2
- CTSE | c.115C>T p.R39W | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs781857257, COSV63059762; called by muse, mutect2, varscan2
- DMD | c.9131A>G p.D3044G | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100628570; called by muse, mutect2, varscan2
- DNAJB5 | c.645C>G p.I215M | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV56624688; called by muse, mutect2, varscan2
- DSG1 | c.1733G>A p.R578H | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.206); catalogued as rs369362154; called by muse, mutect2, varscan2
- ESRRG | c.909T>G p.S303R | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772925003, COSV63150645; called by muse, mutect2, varscan2
- GPC4 | c.254G>A p.S85N | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as COSV63696961; called by muse, mutect2, varscan2
- INA | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 23/29 reads (79%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs1191389159, COSV63975635; called by muse, mutect2, varscan2
- KCNV1 | c.640G>A p.V214I | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765741797, COSV52084728; called by muse, mutect2, varscan2
- KXD1 | c.305T>G p.I102S | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as COSV55889026; called by muse, mutect2, varscan2
- MGAT4A | c.1256G>A p.W419* | Nonsense Mutation (SNP) | VAF 14/111 reads (13%) | catalogued as COSV99384586; called by muse, mutect2, varscan2
- NOL6 | c.2308A>T p.T770S | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV53039404; called by muse, mutect2, varscan2
- NOS1 | c.1714G>A p.V572M | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1412760885, COSV57606502; called by muse, mutect2, varscan2
- ORM2 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.106); catalogued as rs769078483, COSV56335033; called by muse, mutect2, varscan2
- OSBPL1A | c.2152G>T p.G718C (on ENST00000319481 / NM_080597.4; = p.G205C on NM_018030.4) | Missense Mutation (SNP) | VAF 53/105 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60195487; called by muse, mutect2, varscan2
- PCDH11X | c.184C>T p.Q62* | Nonsense Mutation (SNP) | VAF 6/80 reads (8%) | catalogued as COSV100013790; called by muse, mutect2
- PCDHA3 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.728); catalogued as COSV65364814; called by muse, mutect2, varscan2
- PRKCB | c.1199C>T p.P400L | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs764831474, COSV57766972, COSV57792894; called by muse, mutect2, varscan2
- SESTD1 | c.2042T>A p.L681H | Missense Mutation (SNP) | VAF 75/342 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.984); catalogued as COSV58930308; called by muse, mutect2, varscan2
- SPECC1L | c.2495C>T p.S832L | Missense Mutation (SNP) | VAF 20/211 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.914); catalogued as rs760440533, COSV58658195; called by muse, mutect2
- TAF1L | c.4744C>G p.Q1582E | Missense Mutation (SNP) | VAF 36/333 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); catalogued as COSV54270534; called by muse, varscan2
- TAF1L | c.4631C>A p.S1544Y | Missense Mutation (SNP) | VAF 38/225 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767720753, COSV54259847; called by muse, varscan2
- TAF1L | c.3308C>A p.S1103* | Nonsense Mutation (SNP) | VAF 29/169 reads (17%) | catalogued as COSV54264828, COSV99645164; called by muse, mutect2, varscan2
- TAF1L | c.2417C>G p.P806R | Missense Mutation (SNP) | VAF 24/206 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99645168; called by muse, mutect2, varscan2
- TET1 | c.331C>A p.L111I | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV101018655; called by muse, mutect2
- TKTL2 | c.40C>T p.Q14* | Nonsense Mutation (SNP) | VAF 8/41 reads (20%) | catalogued as COSV99761618; called by muse, mutect2
- TLR8 | c.1414C>T p.R472C (on ENST00000218032 / NM_138636.5; = p.R490C on NM_016610.4) | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.528); catalogued as rs1303181160, COSV54318631; called by muse, mutect2
- VPS13B | c.3713A>G p.N1238S | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV62133932; called by muse, mutect2, varscan2
- WDR45B | c.272A>G p.K91R | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV66407787; called by muse, mutect2, varscan2
- WWC3 | c.563T>C p.L188P | Missense Mutation (SNP) | VAF 83/239 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV66501672; called by muse, mutect2, varscan2
- XIRP2 | c.10083A>T p.L3361F (on ENST00000628543; = p.L3536F on NM_152381.6) | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV54683976; called by muse, mutect2, varscan2
- ZNF347 | c.1913C>T p.S638L | Missense Mutation (SNP) | VAF 105/488 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV61967698; called by muse, mutect2, varscan2
- ZZEF1 | c.1444G>A p.A482T | Missense Mutation (SNP) | VAF 66/168 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs745899170, COSV67556093; called by muse, mutect2, varscan2
- HTR7 | c.1257del p.K420Sfs*13 (on ENST00000336152 / NM_019859.4; = p.K420Sfs*28 on NM_000872.5) | Frame Shift Del (DEL) | VAF 7/37 reads (19%) | called by mutect2, pindel, varscan2
- KCNJ3 | c.766A>T p.S256C | Missense Mutation (SNP) | VAF 12/288 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); called by muse, mutect2
- DDX31 | c.2349C>T p.L783= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as rs367878457; called by muse, mutect2, varscan2
- ERCC2 | c.78G>C p.R26= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as COSV55538815; called by muse, mutect2, varscan2
- FCRL3 | c.1086C>T p.N362= | Silent (SNP) | VAF 28/384 reads (7%) | catalogued as rs368325573, COSV63841419; called by muse, mutect2
- FOXA1 | c.483G>A p.T161= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as rs373248780; called by muse, mutect2, varscan2
- LAMA4 | c.1827C>T p.H609= (on ENST00000230538 / NM_001105206.3; = p.H602= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/498 reads (8%) | catalogued as rs1366453433, COSV100039040; called by muse, mutect2
- NDN | c.624C>T p.S208= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs1215274922, COSV100086233, COSV59358388, COSV59359664; called by muse, mutect2
- NECTIN3 | c.198C>T p.V66= | Silent (SNP) | VAF 52/136 reads (38%) | catalogued as COSV60549974; called by muse, mutect2, varscan2
- PPP1R16B | c.522C>T p.C174= | Silent (SNP) | VAF 39/156 reads (25%) | catalogued as rs775908477, COSV55374415; called by muse, mutect2, varscan2
- RAB17 | c.114G>A p.R38= | Silent (SNP) | VAF 14/169 reads (8%) | catalogued as COSV99221404; called by muse, mutect2
- SOCS5 | c.1512C>T p.L504= | Silent (SNP) | VAF 88/162 reads (54%) | catalogued as COSV60603821; called by muse, mutect2, varscan2
- UGT3A2 | c.1461C>T p.D487= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as rs141834822; called by muse, mutect2, varscan2
- WASHC2A | c.2898G>A p.A966= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as COSV50953209; called by mutect2, varscan2
- ADI1 | c.*1C>T | 3'UTR (SNP) | VAF 11/46 reads (24%) | catalogued as rs1003756035, COSV59376306; called by muse, mutect2
- GBA3 | c.59-8060G>A | Intron (SNP) | VAF 84/180 reads (47%) | catalogued as rs375620844; called by muse, mutect2, varscan2
- MIR372 | n.51C>T | RNA (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2
